Somatic mutation profile of tumor specimen TCGA-2X-A9D5-01A (aliquot TCGA-2X-A9D5-01A-11D-A435-10) from TCGA case TCGA-2X-A9D5, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 49.2 years (17,969 days).
Specimen TCGA-2X-A9D5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de0d48e9-dd53-4c71-baa6-b1a696281cc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2X-A9D5-10A (Blood Derived Normal), aliquot TCGA-2X-A9D5-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/043349e2-2516-463c-b9b5-75b2cebf6a92

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 5'UTR 2, Intron 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>G p.N822K | Missense Mutation (SNP) | VAF 35/86 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERCC1 | c.588G>T p.L196F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV50004813; called by muse, mutect2, varscan2
- APOA2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MRAP2 | c.183T>G p.F61L | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLEKHH1 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PTCD3 | c.1636G>C p.V546L | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS45 | c.811T>G p.F271V | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- HECTD4 | c.12379C>T p.L4127= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- HSF2 | c.1089T>C p.Y363= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- SCAF8 | c.3690A>T p.V1230= | Silent (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- SCAP | c.3819T>C p.S1273= | Silent (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- HEXD | c.-3G>A | 5'UTR (SNP) | VAF 43/242 reads (18%) | catalogued as rs1382117709; called by muse, mutect2, varscan2
- KIR2DL4 | c.927+64G>T | Intron (SNP) | VAF 15/61 reads (25%) | catalogued as rs774093859, COSV58490582; called by muse, mutect2, varscan2
- PLK4 | c.-16G>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- TPGS2 | c.657+23T>G | Intron (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
